Gene-level copy-number profile of tumor specimen TARGET-20-PARUCB-04A from TARGET case TARGET-20-PARUCB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,121 days).
Specimen TARGET-20-PARUCB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.c8c5ca7e-da65-5e78-95fc-04c4981f3c37.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARUCB-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate.
https://portal.gdc.cancer.gov/files/0faa5bef-0a82-4aeb-ad2b-7a430e904e53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,389; copy number 1: 1,165; copy number 2: 55,541; copy number 3: 254; copy number 4: 858; copy number 5: 1; copy number 6: 1; copy number 8: 25.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:15,667,236–15,859,771, 1 gene (within-gene range 0–2): ANKRD28.
- chr3:15,738,515–15,738,809, 1 gene: RN7SL4P.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–1): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 2–8): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr18:63,496,989–63,497,400, 1 gene, copy number 5: ATP5MC1P6.
- chr21:16,417,139–16,419,080, 1 gene, copy number 6: AP001172.2.

Autosomal genes at a single copy (total copy number 1): 1,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
